Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3CO, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3CO-01A (Primary Tumor).

[page 1 of 2]
10/15/11

History Case Pathology Report

DOB: _____ Sex: M
Physician: _____

Received: _____

Pathologist: _____

Accession: _____

Case type: Surgical History

**** Case imported from legacy computer system. The format of this report does not match the original case. ****
**** For cases prior to _____, the section "SPECIMEN" may have been added. ****

DIAGNOSIS

- (A) LEFT NECK DISSECTION CONTENTS (LEVEL II, III, IV, AND V):
METASTATIC PAPILLARY THYROID CARCINOMA IN SIX OF TWENTY-ONE LYMPH
NODES (LEVEL II 1/3, LEVEL V 6/18), WITH EXTRANODAL EXTENSION.
(SEE COMMENT).
- (B) RIGHT NECK DISSECTION CONTENTS (LEVEL II, III, IV AND V):
METASTATIC PAPILLARY THYROID CARCINOMA IN THREE OF SEVENTEEN LYMPH
NODES (LEVEL II 0/2, LEVEL V 3/15), WITH EXTRANODAL EXTENSION.
(SEE COMMENT).
- (C) DELPHIAN LYMPH NODE:
METASTATIC PAPILLARY THYROID CARCINOMA IN ONE (3.0 MM GREATEST
DIMENSION) OF THREE LYMPH NODES.
No extranodal extension.
- (D) TOTAL THYROIDECTOMY:
PAPILLARY CARCINOMA OF THYROID GLAND, MULTIFOCAL (LARGEST FOCUS 3.5
CM IN GREATEST DIMENSION) INVOLVING BOTH RIGHT AND LEFT LOBES,
WITH EXTENSION INTO CERVICAL SOFT TISSUE.
No definite vascular invasion.

Entire report and diagnosis completed by: _____
Report released by: _____

COMMENT

The largest lymph node involved by metastatic carcinoma in the left neck dissection (specimen A) measures 2.5 cm in greatest dimension, and is located in level II. There is extranodal extension of tumor from this lymph node.

The largest lymph node involved by metastatic carcinoma in the right neck dissection (specimen B) measures 1.9 cm in greatest dimension, and is located in level V.

GROSS DESCRIPTION

(A) LEFT NECK DISSECTION CONTENTS: LEVEL II, III, IV AND V LYMPH NODE - A neck dissection specimen divided into levels II, III, IV and V by the surgeon. Level II consists of one piece of pink-yellow fibroadipose tissue measuring 4.5 x 2.5 x 2.0 cm. Three lymph nodes are identified. The largest lymph node measures 2.5 x 1.8 x 1.8 cm. Level III consists of one irregular piece of pink-yellow fibroadipose tissue measuring 7.0 x 3.0 x 0.8 cm. No distinctive lymph nodes are identified. Level IV consists of one irregular piece of yellowish adipose tissue measuring 4.5 x 2.0 x 1.0 cm. Four possible lymph nodes are identified. Level V consists of one irregular piece of pink-yellow adipose tissue measuring 5.0 x 3.5 x 2.0 cm. Total of eighteen possible lymph nodes are identified from this level.

Page 1 of 2

100-0-3
Carcinoma, Papillary, thyroid
Site: thyroid, NOS C73.9
8/20/13
10/15/11

[page 2 of 2]
History Case Pathology Report

Department of Pathology,

DOB:
Physician:

Sex: M

Received:

Pathologist:

MD

Accession:

Case type: Surgical History

SECTION CODE: A1-A4, level II lymph nodes (A1, serial sections, one lymph node; A2, one lymph node; A3, and A4, section of largest lymph node); A5, A6, level III representative sections; A7, level IV lymph nodes (four possible lymph nodes); A8-A15, level V lymph nodes (A8, four lymph nodes; A9, two lymph nodes; A10, four lymph nodes; A11, four lymph nodes; A12, sections of one lymph node (submitted after decalcification); A13, one lymph node, bisected; A14, one lymph node, bisected; A15, one lymph node, bisected).

(B) RIGHT NECK DISSECTION CONTENTS (LEVEL II, III, IV, AND V) - A neck dissection specimen divided into levels II, III, IV and V by the surgeon. Level II consists of a fragment of fibrous adipose tissue (4.5 x 4.0 x 0.5 cm), containing tan soft lymph nodes. Level III consists of a fragment of fibroadipose tissue (3.5 x 1.0 x 0.3 cm) with no identifiable lymph nodes. Level IV consists of a fragment of fibroadipose tissue (4.5 x 3.0 x 0.5 cm) with two possible 0.6 cm in diameter lymph nodes. Level V consists of fragments of fibroadipose tissue (8.0 x 5.0 x 0.5 cm) containing twenty possible lymph nodes, up to 1.9 cm in maximum dimension. The largest lymph node is replaced by tumor.

SECTION CODE: Level II (B1-B3): B1, one lymph node, bisected; B2-B3, additional possible lymph nodes, submitted in toto. Level III (B4-B5): B4, two possible lymph nodes, B5, three possible lymph nodes. Level IV (B6, B7): B6, one possible lymph node; B7, two possible lymph nodes. Level V (B8-B19): B8, one lymph node, bisected; B9, one lymph node; B10, one lymph node, bisected; B11, B12, one possible lymph node, bisected; B13, one lymph node; B14, one lymph node, bisected; B15, two lymph nodes; B16, three possible lymph nodes; B17, three possible lymph nodes; B18, four lymph nodes; B19, two lymph nodes.

(C) DELPHIAN NODE - An irregular fragment of pink-gray soft tissue (1.0 x 0.8 x 0.4 cm). Submitted in toto in C.

(D) TOTAL THYROIDECTOMY - A total thyroidectomy specimen (9.0 x 6.0 x 3.5 cm), distorted by a tumor located in the right lobe. This tumor measures 3.5 x 3.5 and 3.0 cm, shows yellowish discoloration and cystic degeneration, and with dark brown fluid. In addition to the largest tumor nodule in the right lobe there is a second nodule (0.6 x 0.5 cm) located 0.2 cm away from the main tumor. In the left lobe there are two small nodules, ranging from 0.3 cm in diameter to 0.6 cm in diameter. The normal appearing thyroid parenchyma is unremarkable.

SECTION CODE: D1, representative section from the left lobe; D2, left lobe nodule; D3, representative section from left lobe; D4, representative section from left lobe; D5-D10, representative section from the large tumor; D11, section from the large tumor and adjacent normal thyroid parenchyma; D12, second nodule in the right lobe; D13, D14, representative section from normal appearing thyroid parenchyma.

SNOMED CODES:

Source: NCI Genomic Data Commons file 350b1c22-7267-447c-8277-435401e3c6c7 (TCGA-EL-A3CO.070A0EB6-F8C7-4F57-B655-137ED40B4A12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).